Somatic mutation profile of tumor specimen C3L-02961-01 (aliquot CPT0196950006) from CPTAC case C3L-02961, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA2; Tumor grade: G2; Age at diagnosis: 70.2 years (25,640 days).
Specimen C3L-02961-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 037b3333-dce8-4917-9125-93c0f3273b3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02961-31 (Blood Derived Normal), aliquot CPT0197800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59ca1935-88d6-4d8e-8d10-f2946a3bd90f

The open-access MAF lists 175 somatic variants for this specimen: 127 protein-altering or splice-affecting, 36 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 36, Nonsense Mutation 7, Frame Shift Del 6, 5'UTR 4, Splice Site 4, Intron 4, Frame Shift Ins 2, 3'UTR 2, Splice Region 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 44/148 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC5A1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs201799893, CM110176, COSV56683485; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- STK11 | c.374+1A>G p.X125_splice | Splice Site (SNP) | VAF 39/98 reads (40%) | hotspot (GDC flag); catalogued as rs1131690951, CS021376, COSV58820569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG1 | c.2030A>G p.D677G | Missense Mutation (SNP) | VAF 88/474 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs771773781; called by muse, mutect2, varscan2
- ANKS1B | c.1525C>A p.P509T | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61335100; called by muse, mutect2, varscan2
- C10orf71 | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs930161211, COSV60508565; called by muse, mutect2, varscan2
- CA8 | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58771322; called by muse, mutect2, varscan2
- CDH6 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 42/443 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV54065519; called by muse, mutect2
- CHN1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.424); catalogued as rs1439551726, COSV69295381; called by muse, mutect2, varscan2
- CRADD | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.514); catalogued as rs746685035, COSV100257287, COSV60552839; ClinVar: uncertain significance; called by muse, mutect2
- DIDO1 | c.6119G>A p.R2040H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.379); catalogued as rs143474883; called by muse, mutect2, varscan2
- DMBX1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs375524919; called by muse, mutect2, varscan2
- DPP3 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as rs535853041, COSV100855607; called by muse, mutect2, varscan2
- DUS2 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371314679; called by muse, mutect2, varscan2
- ETNK2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 47/410 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV65817662; called by muse, mutect2, varscan2
- FAM124A | c.869G>T p.G290V (on ENST00000322475 / NM_001242312.2; = p.G326V on NM_145019.4) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as COSV54476525; called by muse, mutect2, varscan2
- FDXR | c.863C>T p.P288L (on ENST00000293195 / NM_024417.5; = p.P294L on NM_004110.6) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as rs1333750621; called by muse, mutect2, varscan2
- GPR174 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 56/240 reads (23%) | catalogued as rs1333054510, COSV52133979; called by muse, mutect2, varscan2
- HDGF | c.164+3G>C | Splice Region (SNP) | VAF 19/210 reads (9%) | catalogued as rs113283548; called by muse, mutect2
- HDX | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV52976765; called by muse, mutect2, varscan2
- IGFN1 | c.2411C>T p.T804M (on ENST00000295591 / NM_001367841.1; = p.T3261M on NM_001164586.2) | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs755243413, COSV99813891; called by muse, mutect2, varscan2
- MAOB | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100956036; called by muse, mutect2, varscan2
- MTFMT | c.1059G>T p.W353C | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1354264543; called by muse, mutect2, varscan2
- NEU4 | c.227C>A p.T76K (on ENST00000391969 / NM_001167602.3; = p.T88K on NM_080741.4) | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV57991226; called by muse, mutect2, varscan2
- NFATC4 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV51596793, COSV51599783; called by muse, mutect2, varscan2
- OR2J3 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV65848668; called by muse, mutect2
- OR4A5 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as COSV60523332; called by muse, mutect2, varscan2
- OR4C11 | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565082722, COSV100155250; called by muse, mutect2, varscan2
- PDE1C | c.1622T>G p.L541R | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs754052344; called by muse, mutect2, varscan2
- PIM2 | c.898G>T p.G300* | Nonsense Mutation (SNP) | VAF 50/110 reads (45%) | catalogued as COSV99900018; called by muse, mutect2, varscan2
- RAG1 | c.2968G>C p.V990L | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV100201072; called by muse, mutect2, varscan2
- RNF213 | c.14935C>G p.L4979V | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60407587; called by muse, mutect2, varscan2
- RYR2 | c.12173A>G p.Y4058C | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63686081; called by muse, mutect2
- RYR3 | c.12782C>A p.T4261N (on ENST00000389232; = p.T4262N on NM_001036.6) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as rs765319074; called by muse, mutect2, varscan2
- SF1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV57111728; called by muse, mutect2, varscan2
- SLC2A14 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as rs778525180, COSV61585472; called by muse, varscan2
- ST3GAL2 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 35/264 reads (13%) | PolyPhen benign (0.082); catalogued as rs751720119; called by muse, mutect2, varscan2
- TENM2 | c.4573del p.D1525Mfs*19 (on ENST00000518659 / NM_001122679.2; = p.D1286Mfs*19 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 42/185 reads (23%) | catalogued as COSV69128251; called by mutect2, pindel, varscan2
- TSC2 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 20/564 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs983899092, COSV54782663; called by muse, mutect2
- USP17L1 | c.993C>A p.H331Q | Missense Mutation (SNP) | VAF 193/802 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as rs374439010; called by muse, mutect2, varscan2
- VPS51 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 53/161 reads (33%) | catalogued as COSV54206868; called by muse, mutect2, varscan2
- ZFHX4 | c.6409A>T p.T2137S | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV51494754; called by muse, mutect2, varscan2
- ZNF347 | c.246G>T p.W82C | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.187); catalogued as COSV100498130; called by muse, mutect2, varscan2
- ZNF423 | c.1654G>C p.G552R (on ENST00000563137 / NM_001379286.1; = p.G544R on NM_015069.4) | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV99282495; called by muse, mutect2, varscan2
- ZNF438 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as COSV59198076; called by muse, mutect2, varscan2
- ADAMTS18 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ARAP2 | c.4400T>G p.F1467C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL3 | c.5929C>A p.L1977I | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATG13 | c.797G>T p.S266I | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ATP7A | c.2481del p.D828Ifs*23 | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | called by mutect2, pindel, varscan2
- BCHE | c.1320G>T p.W440C | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- BEND5 | c.634del p.V212Yfs*17 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | called by mutect2, pindel, varscan2
- COL18A1 | c.3546C>A p.S1182R (on ENST00000359759 / NM_130444.3; = p.S947R on NM_030582.4) | Missense Mutation (SNP) | VAF 98/395 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.068); called by mutect2, varscan2
- DALRD3 | c.728A>G p.D243G (on ENST00000341949 / NM_001009996.3; = p.D76G on NM_018114.5) | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ERICH3 | c.560C>A p.S187* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- FAM171B | c.2326_2342del p.G776Kfs*6 | Frame Shift Del (DEL) | VAF 20/248 reads (8%) | called by mutect2, pindel
- FAM228B | c.360+2T>C p.X120_splice | Splice Site (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- FAM83B | c.1498T>G p.Y500D | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAT3 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FMN2 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); called by muse, mutect2
- FPGT-TNNI3K | c.1384T>G p.C462G | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- FRMPD4 | c.1546G>T p.V516F | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GAL3ST4 | c.1300G>T p.V434F | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GCM2 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 174/718 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- GPR12 | c.411C>A p.D137E | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2
- GPR135 | c.396del p.Q133Sfs*103 | Frame Shift Del (DEL) | VAF 70/376 reads (19%) | called by mutect2, pindel, varscan2
- GRAMD1C | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2
- GRID2 | c.935C>A p.P312Q | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- HCN1 | c.2672G>T p.*891Lext*15 | Nonstop Mutation (SNP) | VAF 97/388 reads (25%) | called by muse, mutect2, varscan2
- HRC | c.193A>G p.R65G | Missense Mutation (SNP) | VAF 107/371 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA2 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- IGFL1 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- INPP5J | c.1612-1G>A p.X538_splice (on ENST00000331075 / NM_001284285.2; = p.X170_splice on NM_001002837.2) | Splice Site (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2
- IRS2 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- JHY | c.17del p.L6Qfs*16 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- KBTBD8 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNJ5 | c.938-1G>T p.X313_splice | Splice Site (SNP) | VAF 100/343 reads (29%) | called by muse, mutect2, varscan2
- KEAP1 | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 113/249 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KPNA2 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRP2 | c.8518T>C p.Y2840H | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRRC3C | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRIQ1 | c.4746C>A p.F1582L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- LY75 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MAGEL2 | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MLLT10 | c.1360C>G p.Q454E | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); called by muse, mutect2
- MTFMT | c.1058G>T p.W353L | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- MTMR1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MXRA5 | c.7144T>A p.S2382T | Missense Mutation (SNP) | VAF 72/294 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYO18A | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- N4BP2L2 | c.2754G>T p.K918N (on ENST00000674422; = p.K489N on NM_033111.4) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NDUFA4L2 | c.43A>C p.K15Q | Missense Mutation (SNP) | VAF 119/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NUDT12 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR52L1 | c.673A>T p.I225F | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.161); called by muse, mutect2
- PIK3R4 | c.2476A>C p.I826L | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD1 | c.4602C>G p.S1534R | Missense Mutation (SNP) | VAF 105/312 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POFUT2 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POLRMT | c.1942A>T p.M648L | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PORCN | c.649T>C p.Y217H | Missense Mutation (SNP) | VAF 29/506 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.105); called by muse, mutect2
- PRDM9 | c.1615G>T p.V539F | Missense Mutation (SNP) | VAF 117/456 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PSG5 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.356); called by muse, mutect2
- PTX4 | c.1427G>C p.R476P (on ENST00000447419 / NM_001328608.2; = p.R471P on NM_001013658.1) | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RAB9B | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- RADX | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAG1 | c.1153A>T p.I385F | Missense Mutation (SNP) | VAF 66/569 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAX | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- RPL9 | c.181_183del p.W61del | In Frame Del (DEL) | VAF 59/349 reads (17%) | called by pindel, varscan2
- RRP12 | c.3061A>T p.K1021* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | called by muse, varscan2
- RYR2 | c.3346G>C p.G1116R | Missense Mutation (SNP) | VAF 189/468 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SCN11A | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SF1 | c.132dup p.T45Yfs*20 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- SLC5A1 | c.1303G>C p.G435R | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); called by muse, mutect2
- SMG8 | c.1563G>T p.M521I | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- SMG9 | c.1235A>T p.N412I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ST8SIA3 | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 26/450 reads (6%) | PolyPhen benign (0.003); called by muse, mutect2
- TASOR2 | c.2648C>T p.T883I | Missense Mutation (SNP) | VAF 83/322 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TBX22 | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD9 | c.1296A>T p.L432F | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TENM1 | c.8107C>T p.Q2703* | Nonsense Mutation (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- TKTL1 | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.314); called by muse, mutect2
- TTN | c.94744C>A p.R31582S (on ENST00000591111; = p.R24158S on NM_003319.4) | Missense Mutation (SNP) | VAF 30/132 reads (23%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UPF3B | c.1336G>T p.A446S (on ENST00000276201 / NM_080632.3; = p.A433S on NM_023010.3) | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- USP29 | c.1272dup p.V425Cfs*3 | Frame Shift Ins (INS) | VAF 60/339 reads (18%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.9842C>T p.T3281I | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- ZNF100 | c.754A>T p.R252W | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ZNF568 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZNF93 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARHGAP17 | c.2625T>C p.D875= (on ENST00000289968 / NM_001006634.3; = p.D797= on NM_018054.6) | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs1348843885, COSV51509328; called by muse, mutect2, varscan2
- CELF4 | c.840G>A p.A280= | Silent (SNP) | VAF 52/177 reads (29%) | catalogued as rs372009828; called by muse, mutect2, varscan2
- CFAP47 | c.2559T>C p.S853= | Silent (SNP) | VAF 78/207 reads (38%) | called by muse, mutect2, varscan2
- CFAP47 | c.6843T>C p.P2281= | Silent (SNP) | VAF 59/237 reads (25%) | called by muse, mutect2, varscan2
- CHM | c.222G>T p.V74= | Silent (SNP) | VAF 59/214 reads (28%) | called by muse, mutect2, varscan2
- FMR1NB | c.174G>T p.R58= | Silent (SNP) | VAF 159/415 reads (38%) | called by muse, mutect2, varscan2
- GABRG3 | c.789C>A p.P263= | Silent (SNP) | VAF 58/155 reads (37%) | called by muse, mutect2, varscan2
- GPRASP2 | c.168T>G p.S56= | Silent (SNP) | VAF 41/417 reads (10%) | called by muse, mutect2, varscan2
- IL17RE | c.912C>T p.C304= | Silent (SNP) | VAF 41/247 reads (17%) | catalogued as rs1448691293; called by muse, mutect2, varscan2
- KIF5A | c.3093C>T p.A1031= | Silent (SNP) | VAF 13/453 reads (3%) | called by muse, mutect2
- KLHL13 | c.1095G>A p.K365= | Silent (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2, varscan2
- KLHL33 | c.9G>T p.L3= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- KRT35 | c.87C>T p.S29= | Silent (SNP) | VAF 22/229 reads (10%) | catalogued as rs769176495; called by muse, mutect2
- LRBA | c.501C>T p.R167= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs763929621, COSV63958505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MVD | c.933G>A p.V311= | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- NALCN | c.4770G>T p.S1590= | Silent (SNP) | VAF 56/184 reads (30%) | catalogued as COSV51948939; called by muse, mutect2, varscan2
- NUP107 | c.369A>G p.T123= | Silent (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- OR52L1 | c.828C>A p.S276= | Silent (SNP) | VAF 87/292 reads (30%) | called by muse, mutect2, varscan2
- OR5D18 | c.738G>T p.L246= | Silent (SNP) | VAF 52/179 reads (29%) | called by muse, mutect2, varscan2
- OR6X1 | c.228C>A p.I76= | Silent (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- OXTR | c.333G>A p.L111= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs375980749; called by muse, mutect2, varscan2
- PFAS | c.3132C>T p.C1044= | Silent (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- PPEF1 | c.153T>A p.A51= | Silent (SNP) | VAF 65/226 reads (29%) | called by muse, mutect2, varscan2
- PTCH2 | c.1200A>G p.G400= | Silent (SNP) | VAF 99/382 reads (26%) | called by muse, mutect2, varscan2
- PTPN6 | c.300G>A p.L100= | Silent (SNP) | VAF 40/240 reads (17%) | called by muse, mutect2, varscan2
- RIMS2 | c.2187A>G p.G729= (on ENST00000666250 / NM_001348490.2; = p.G537= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs770720804; called by mutect2, varscan2
- SCART1 | c.1579C>A p.R527= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- SNTG2 | c.615C>A p.P205= | Silent (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- TAC3 | c.342C>G p.L114= | Silent (SNP) | VAF 57/424 reads (13%) | catalogued as rs779944286; called by muse, mutect2, varscan2
- TRERF1 | c.816G>A p.P272= | Silent (SNP) | VAF 132/415 reads (32%) | catalogued as rs139517363; called by muse, mutect2, varscan2
- TRHDE | c.888A>T p.A296= | Silent (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- TRIM58 | c.1347C>T p.F449= | Silent (SNP) | VAF 47/307 reads (15%) | catalogued as COSV63569018; called by muse, mutect2, varscan2
- UBE2O | c.3252C>T p.F1084= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs957453169, COSV60063887; called by muse, mutect2
- URB2 | c.4512C>G p.L1504= | Silent (SNP) | VAF 22/364 reads (6%) | called by muse, mutect2
- ZNF540 | c.1503G>A p.G501= | Silent (SNP) | VAF 48/233 reads (21%) | called by muse, mutect2, varscan2
- ZNF768 | c.1188C>T p.T396= | Silent (SNP) | VAF 30/314 reads (10%) | catalogued as rs746406526; called by muse, mutect2
- CASP16P | chr16:3147815 C>A | 3'Flank (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- COG6 | c.*795G>C | 3'UTR (SNP) | VAF 32/317 reads (10%) | called by muse, mutect2, varscan2
- GANC | c.201+2389C>T | Intron (SNP) | VAF 50/193 reads (26%) | called by muse, mutect2, varscan2
- HLA-C | c.1048+25G>T | Intron (SNP) | VAF 138/347 reads (40%) | called by muse, mutect2, varscan2
- IL34 | c.-56G>T | 5'UTR (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- NACA | c.71-4467T>C | Intron (SNP) | VAF 46/198 reads (23%) | called by muse, mutect2, varscan2
- PAX5 | c.-3A>T | 5'UTR (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- RCC1 | c.-276C>T | 5'UTR (SNP) | VAF 54/202 reads (27%) | catalogued as rs748493338; called by muse, mutect2, varscan2
- SAV1 | c.94+487G>C | Intron (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- SHROOM2 | c.*2471G>T | 3'UTR (SNP) | VAF 59/184 reads (32%) | catalogued as COSV66607636; called by muse, mutect2, varscan2
- SSPOP | n.14363G>A | RNA (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- TRPM1 | c.-19C>A | 5'UTR (SNP) | VAF 41/112 reads (37%) | called by muse, mutect2, varscan2
